Surgical pathology report (de-identified scan), TCGA case TCGA-DK-A3IK, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-A3IK-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT (

Patient Name:

Med. Rec. #:

DOB: (Age:)

Gender: M

Ref. Physician:

Patient Address:

Ref. Source:

Location:

Service: Private Outpatient

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

OUTPATIENT

Additional Copy to:

Clinical Diagnosis & History:

Bladder cancer

Specimens Submitted:

- 1: Right common iliac lymph nodes (fs)
- 2: Left pelvic lymph nodes #1 (fs)
- 3: Left pelvic lymph nodes #2
- 4: Bladder, prostate seminal vesicles
- 5: Left common iliac lymph node
- 6: Right vas deferens
- 7: Left vas deferens
- 8: Right common iliac lymph nodes
- 9: Right pelvic lymph nodes
- 10: Pre-sacral lymph node
- 11: Right ureter, excision

ICD-0-3

carcinoma, urothelial, NOS 8120/3
Path Site: bladder, wall, posterior c67.4
CQCF: bladder, wall, lateral c67.2

hw
12/8/11

DIAGNOSIS:

1. Right common iliac lymph nodes (fs):

Part # 1

Lymph Node Dissection:

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 2

Size of the largest lymph node involved by tumor: 0.9cm.

Size of the largest metastatic focus : 0.9 cm.

Extranodal extension is identified

2. Left pelvic lymph nodes #1 (fs):

Part # 2

Lymph Node Dissection:

Number of lymph nodes examined: 2

Number of lymph nodes with metastatic disease: 2

Size of the largest lymph node involved by tumor: 1cm.

Size of the largest metastatic focus : 1 cm.

Extranodal extension is identified

3. Left pelvic lymph nodes #2:

Part # 3

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 6

4. Bladder, prostate seminal vesicles:

Part # 4

Tumor Type:

Urothelial carcinoma with squamous differentiation

Invasive urothelial carcinoma, NOS, with clear cell and squamoid features

Histologic Grade:

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

High grade
Pattern of growth of the Non-Invasive component:
Papillary and flat
Pattern of growth of the Invasive component:
Infiltrating
Tumor Multicentricity:
Identified
Bladder Local Invasion:
Perivesical soft tissues
Extravesical Tumor Extension:
Urethra involved
Periurethral prostatic ducts involved
Vascular Invasion:
Identified (extensive)
Perineural Invasion:
Identified
Surgical Margins:
Free of tumor

Non-Neoplastic Mucosa:
Exhibiting chronic cystitis
Exhibiting ulceration
Prostate:
Other ; high grade prostatic intraepithelial neoplasia (PIN)
Seminal Vesicles:
Not involved
Perivesical Lymph Nodes:
Not identified
The Pathologic Stage is (AJCC 2002):
pT3 (Invasion of perivesicle soft tissue)

PRis (Involvement of urethra or prostatic ducts without stromal invasion)

5. Left common iliac lymph node:

Part # 5

Lymph Node Dissection:

Number of lymph nodes examined: 1
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 0.6cm.
Size of the largest metastatic focus : 0.6 cm.
Extranodal extension is not identified

6. Right vas deferens, excision:

Benign vas deferens

7. Left vas deferens, excision:

Benign vas deferens

8. Right common iliac lymph nodes:

Part # 8

Lymph Node Dissection:

Number of lymph nodes examined: 3
Number of lymph nodes with metastatic disease: 1
Size of the largest lymph node involved by tumor: 1.7cm.
Size of the largest metastatic focus : 0.8 cm.
Extranodal extension is not identified

9. Right pelvic lymph nodes:

Part # 9

Lymph Node Dissection:

Number of lymph nodes examined: 12
Number of lymph nodes with metastatic disease: 2
Size of the largest lymph node involved by tumor: 0.5cm.
Size of the largest metastatic focus : 0.5 cm.

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Extranodal extension is not identified

10. Pre-sacral lymph node:

Part # 10

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

11. Right ureter, excision:

Benign ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section, labeled "Right common iliac lymph nodes" and consists of two pink tan firm lymph nodes averaging 1.0 cm in greatest dimension. The lymph nodes are bisected and submitted.

Summary of sections: FSC--frozen section control, PLN--possible lymph node

2). The specimen is received fresh for frozen section consultation, labeled "Left pelvic lymph nodes #1" and consists of a 2cm lymph node. The specimen is representatively submitted for frozen section, the remaining is given to TPS protocol. Multiple lymphoid fragments are identified on the container measuring 2.5 x 1.4 x 0.5 cm in aggregate, entirely submitted for permanent section. Summary of sections: FSC - frozen section control, RT - remaining tissue

3). The specimen is received in formalin, labeled "Left pelvic lymph node #2" and consists of six pink tan firm, fatty lymph nodes ranging from 1 to 2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN - lymph nodes, BLN - bisected lymph node

4). The specimen is received fresh labeled, "bladder, prostate, seminal vesicles ". It consists of a bladder measuring 6 cm from superior to inferior, 8 cm laterally and 9 cm from anterior to posterior and a prostate measuring 3 cm from superior to inferior, 3 cm laterally and 2 cm from anterior to posterior. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal an ulcerated discoid lesion measuring 8 x 6 cm which is grossly situated within the left posterior wall and extended to the left anterior wall. The lesion involves the left and right ureteral orifices. Both ureters are probe patent, measuring up to 0.2 cm in maximum diameter. The lesion is sectioned to reveal it extends to the fat. The remaining bladder mucosa is thickened and edematous. Discrete perivesical lymph nodes are grossly not identified. The prostate is serially sectioned to reveal white nodular cut surfaces. Representative sections are submitted including two sections from each prostatic quadrant and transition zone. TPS is submitted.

Summary of sections: UTHM - urethral margin, RUM - right ureter margin, LUM - left ureter margin, L - lesion
RUO - right ureter orifice, LUO - left ureter orifice, LP - left posterior wall, LA - left anterior wall, RP - right posterior wall
RA - right anterior wall, TRI - trigone, DOM - dome, F - perivesical fat, RSV - right seminal vesicle, LSV - left seminal vesicle
RAP - right apex prostate, LAP - left apex prostate, RPM - right posterior mid prostate, RAM - right anterior mid prostate
LAM - left anterior mid prostate, LPM - left posterior mid prostate, RAB - right anterior base prostate
RPB - right posterior base prostate, LAB - left anterior base prostate, LPB - left posterior base prostate
ADD - additional sections of the prostate

5). The specimen is received in formalin, labeled "Left common iliac lymph nodes" and consists of two pink tan firm, fatty lymph nodes measuring 0.7 and 0.8 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN - lymph node, BLN - bisected lymph node

6). The specimen is received in formalin, labeled "Right vas deferens" and consists of a tubular piece of tan elastic tissue, measuring 6.5 cm in length and 0.4 cm in average diameter. Representatively submitted.

Summary of sections: BE - both ends, RS - representative sections

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

7). The specimen is received in formalin, labeled "Left vas deferens" and consists of a tubular piece of tan elastic tissue, measuring 4.5 cm in length and 0.3 cm in average diameter. Representatively submitted.

Summary of sections: BE - both ends, RS – representative sections

8). The specimen is received in formalin, labeled "Right common iliac lymph nodes" and consists of three pink tan firm lymph nodes ranging from 0.6 to 1.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN - lymph nodes, BLN - bisected lymph node

9). The specimen is received in formalin, labeled "right pelvic lymph nodes" and consists of multiple pink tan, fatty lymph nodes ranging from 0.3 to 1.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN - lymph nodes, BLN - bisected lymph nodes

10). The specimen is received in formalin, labeled "Presacral lymph nodes" and consists of six pink tan firm, fatty lymph nodes ranging from 1 to 7 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections: LN - lymph nodes, TLN - trisected lymph node

11). The specimen is received in formalin, labeled "Right ureter" and consists of an unoriented tubular piece of tan elastic tissue, with attached small amount of fat measuring 3.5 cm in length. There is a dilated end which measure 0.8 cm in diameter, the opposite end measures 0.6 cm. Representatively submitted.

Summary of sections: DE – dilated end, OE – opposite end, RS – representative sections

Summary of Sections:

Part 1: Right common iliac lymph nodes (fs)

Block	Sect. Site	PCs
1	{not entered}	1
1	FSC	1
1	PLN	1

Part 2: Left pelvic lymph nodes #1 (fs)

Block	Sect. Site	PCs
1	FSC	1
1	RT	1

Part 3: Left pelvic lymph nodes # 2

Block	Sect. Site	PCs
1	BLN	2
3	LN	4

Part 4: Bladder, prostate seminal vesicles

Block	Sect. Site	PCs
6	ADD	6
1	DOM	0
1	F	0
8	L	0
1	LA	0
1	LAB	0
1	LAM	0
1	LAP	0
1	LP	0
1	LPB	0
1	LPM	0
1	LSV	0
1	LUM	0
1	LUO	0

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

1	RA	0
1	RAB	0
1	RAM	0
1	RAP	0
1	RP	0
1	RPB	0
1	RPM	0
1	RSV	0
1	RUM	0
1	RUO	0
1	TRI	0
1	UTHM	0

Part 5: Left common iliac lymph node

Block	Sect. Site	PCs
1	BLN	2
1	LN	1

Part 6: Right vas deferens

Block	Sect. Site	PCs
1	BE	1
1	RS	1

Part 7: Left vas deferens

Block	Sect. Site	PCs
1	BE	2
1	RS	4

Part 8: Right common iliac lymph nodes

Block	Sect. Site	PCs
1	BLN	2
1	LN	2

Part 9: Right pelvic lymph nodes

Block	Sect. Site	PCs
2	BLN	4
5	LN	14

Part 10: Pre-sacral lymph node

Block	Sect. Site	PCs
2	LN	4
2	TLN	2

Part 11: Right ureter, excision

Block	Sect. Site	PCs
1	DE	1
1	OE	1
1	RS	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1. Frozen section diagnosis: Right common iliac lymph nodes (fs): Metastatic carcinoma ().
Permanent diagnosis: Same
2. Frozen section diagnosis: Left pelvic lymph nodes #1(fs): Metastatic carcinoma .
Permanent diagnosis: Same

Source: NCI Genomic Data Commons file a5e3b579-f409-43d8-8272-5e47d0750dcd (TCGA-DK-A3IK.4BB6EAAF-643A-43F8-A54C-0103A45AD684.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).